Somatic mutation profile of tumor specimen TCGA-KS-A41L-01A (aliquot TCGA-KS-A41L-01A-11D-A23M-08) from TCGA case TCGA-KS-A41L, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.5 years (14,440 days).
Specimen TCGA-KS-A41L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd35bcf3-7466-4853-814f-0c44a2e6cd2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A41L-11A (Solid Tissue Normal), aliquot TCGA-KS-A41L-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/988de7e6-5f23-4a83-a264-c81e03daf0cb

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.241); catalogued as COSV55846340, COSV99695442; called by muse, mutect2
- CALCR | c.682G>A p.V228M (on ENST00000649521 / NM_001164737.2; = p.V212M on NM_001742.4) | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761921361, COSV100810538, COSV64006457; called by muse, mutect2
- JAK2 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371826393; called by muse, mutect2, varscan2
- KRBA2 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV100497651; called by muse, mutect2, varscan2
- SIGLEC12 | c.1348A>T p.N450Y (on ENST00000291707 / NM_053003.4; = p.N332Y on NM_033329.2) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV99389311; called by muse, mutect2, varscan2
- SPATA13 | c.468G>T p.W156C | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100542165; called by muse, mutect2, varscan2
- EOLA2 | c.183C>A p.L61= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV100778055; called by muse, mutect2
- LRP1 | c.4008G>A p.E1336= | Silent (SNP) | VAF 48/159 reads (30%) | catalogued as COSV99675591; called by muse, mutect2, varscan2
- PGM1 | c.1263C>T p.G421= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV100936571; called by muse, mutect2
